Gene-level copy-number profile of tumor specimen TCGA-31-1959-01A from TCGA case TCGA-31-1959, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 50.0 years (18,247 days).
Specimen TCGA-31-1959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.71d66a83-6c0b-4d65-bfc1-39c00b4d09cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-31-1959-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e88ddce-72ad-46f5-a408-ace3fc5981ae

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 29,940; copy number 2: 25,833; copy number 3: 2,929; copy number 4: 673; copy number 5: 276; copy number 6: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-31-1959-01A-01D-0648-01): tumor purity 0.66, ploidy 1.58, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:89,111,533–97,135,059, 57 genes: TIGD2, AC104785.1, RNU6-907P, GPRIN3, AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1, CCSER1, RN7SKP248, AC093729.1, TMSB4XP8, AC004054.1, AC074124.1, AC110774.1, KRT19P6, AC093810.1, PMPCAP1, AC097520.2, AC097520.1, LNCPRESS2, AC112695.1, GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B, UNC5C, AC106881.1, RPL30P6, PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28, AC096585.1, COX7A2P2, AC108515.1.
- chr4:97,334,635–97,633,823, 2 genes (within-gene range 0–1): AC034154.1, STPG2-AS1.
- chr4:173,419,245–173,659,696, 7 genes (within-gene range 0–1): RPL5P11, AC093849.3, RNU6-1096P, AC093849.1, AC093849.2, HAND2, HAND2-AS1.
- chr7:127,857,852–127,858,488, 1 gene: AC006529.1.
- chr11:134,331,874–135,075,908, 14 genes: GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,946 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,433,492–41,484,683, 190 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr1:41,535,443–41,628,816, 3 genes, copy number 3: AL445933.2, AL445933.1, AC119676.1.
- chr1:63,440,770–63,660,245, 14 genes, copy number 3: ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P.
- chr1:63,788,721–63,843,685, 2 genes, copy number 3: AL161742.1, CFL1P3.
- chr2:38,814–23,381,299, 341 genes, copy number 4–6 (broad region; genes not listed).
- chr2:23,507,043–23,524,344, 1 gene, copy number 4: AC011239.1.
- chr2:45,651,345–63,891,562, 272 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:127,638,381–132,671,579, 190 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:188,598,791–189,012,746, 6 genes, copy number 3: AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606.
- chr3:151,565,876–198,222,513, 814 genes, copy number 3–5 (broad region; genes not listed).
- chr4:51,843,000–74,303,099, 356 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:41,250,851–41,895,361, 26 genes, copy number 4 (within-gene range 2–4): AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2.
- chr7:18,026,770–19,002,416, 4 genes, copy number 3 (within-gene range 2–3): PRPS1L1, HDAC9, MIR1302-6, AC010082.1.
- chr8:113,950,886–128,187,101, 192 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr8:139,727,725–145,066,685, 207 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr11:42,939,775–45,388,511, 55 genes, copy number 3: AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2, ALX4, AC010768.4, AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687.
- chr11:45,397,590–45,412,745, 2 genes, copy number 3: AC018716.2, AC018716.1.
- chr11:72,002,864–72,080,693, 1 gene, copy number 3 (within-gene range 2–3): NUMA1.
- chr11:72,047,873–72,843,674, 44 genes, copy number 3: RNU6-72P, MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2.
- chr11:72,869,544–72,869,650, 1 gene, copy number 3: RNU6-672P.
- chr11:116,609,995–118,088,299, 43 genes, copy number 3 (within-gene range 2–3): AP000770.1, LINC02702, BUD13, AP006216.1, ZPR1, APOA5, AP006216.2, AP006216.3, APOA4, APOC3, APOA1, APOA1-AS, SIK3, RNY4P6, AP000936.3, AP000936.1, AP000936.2, AP005018.2, AP005018.1, PAFAH1B2, SIDT2, TAGLN, PCSK7, AP000892.4, RNF214, AP000892.2, BACE1, BACE1-AS, AP000892.3, CEP164, AP000892.1, PRR13P3, DSCAML1, AP000711.1, AP001554.1, FXYD2, AP000757.2, FXYD6-FXYD2, AP000757.1, FXYD6, TMPRSS13, IL10RA, SMIM35.
- chr12:66,767–29,784,759, 744 genes, copy number 3–5 (broad region; genes not listed).
- chr14:95,157,645–99,272,197, 73 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr15:90,966,040–101,933,350, 232 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr16:3,930,806–9,518,325, 116 genes, copy number 3 (broad region; genes not listed).
- chr20:62,231,922–62,551,526, 16 genes, copy number 4 (within-gene range 2–4): OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1.
- chr20:62,554,306–62,554,376, 1 gene, copy number 4: MIR1-1.

Autosomal genes at a single copy (total copy number 1): 27,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
